Gene-level copy-number profile of tumor specimen MP2PRT-PATEMR-TMP1-A from MP2PRT case MP2PRT-PATEMR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.3 years (3,770 days).
Specimen MP2PRT-PATEMR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6e3802a9-ecab-400e-beaf-5d264fcff5ea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATEMR-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,398 have no estimate.
https://portal.gdc.cancer.gov/files/cc487e37-24a9-4267-819b-444e3bb79281

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 676; copy number 1: 4,510; copy number 2: 49,931; copy number 3: 3,108.

Homozygous deletions (total copy number 0; autosomes only): 492 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,254,015, 43 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,947,512–89,990,221, 5 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,209,873–90,235,370, 3 genes: IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr4:148,819,351–148,942,415, 2 genes: AC093648.1, AC002460.1.
- chr7:142,636,924–142,802,748, 29 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr11:5,689,697–5,737,089, 3 genes (within-gene range 0–2): TRIM22, OR52U1P, OR52P1P.
- chr12:11,649,674–11,895,377, 1 gene: ETV6.
- chr14:105,672,308–106,704,286, 162 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:39,472,703–45,167,526, 234 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,366,210–22,404,721, 9 genes: ASH2LP2, IGLV7-46, AC245291.3, IGLV5-45, IGLV1-44, IGLV7-43, IGLVI-42, IGLVVII-41-1, IGLV1-41.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,350. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
